Somatic mutation profile of tumor specimen TCGA-CD-8536-01A (aliquot TCGA-CD-8536-01A-11D-2340-08) from TCGA case TCGA-CD-8536, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 74.8 years (27,328 days).
Specimen TCGA-CD-8536-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ee77b62-7876-4b8b-9b9c-032f410ba5e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8536-10A (Blood Derived Normal), aliquot TCGA-CD-8536-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68e88c9f-95bb-44ef-b09c-15c93a89ec38

The open-access MAF lists 1,044 somatic variants for this specimen: 827 protein-altering or splice-affecting, 197 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 536, Silent 197, Frame Shift Del 193, Frame Shift Ins 39, Nonsense Mutation 31, Splice Site 16, Intron 13, In Frame Del 8, Splice Region 3, 5'UTR 2, 3'UTR 2, 3'Flank 2.

Variants (750 of 1,044; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4726G>T p.E1576* | Nonsense Mutation (SNP) | VAF 51/207 reads (25%) | catalogued as rs1554086134, COSV57334276, COSV57398676; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GFAP | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs61622935, CM013268, CM013269, COSV53650717; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 28/157 reads (18%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KIAA0586 | c.-8del | 5'UTR (DEL) | VAF 13/49 reads (27%) | catalogued as rs745949846; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 33/154 reads (21%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MRPS2 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs201229537, COSV54093017; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs730880878, CM081345, COSV62519342; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 14/115 reads (12%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 27/65 reads (42%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- RP1 | c.3843dup p.P1282Sfs*2 | Frame Shift Ins (INS) | VAF 46/308 reads (15%) | catalogued as rs769601671; ClinVar: pathogenic; called by mutect2, varscan2
- SCN1A | c.2665del p.A889Lfs*5 (on ENST00000303395 / NM_001202435.3; = p.A878Lfs*5 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/154 reads (23%) | catalogued as rs1559200672, COSV57667692; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SGCA | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.727); catalogued as rs371675217, CM163140, CM951149, COSV56249347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC12A1 | c.1163del p.F388Sfs*40 | Frame Shift Del (DEL) | VAF 32/158 reads (20%) | catalogued as rs779588655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 19/101 reads (19%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA12 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs753119888, COSV55959745; called by muse, mutect2, varscan2
- ABCC10 | c.3754G>A p.V1252M (on ENST00000372530 / NM_001198934.2; = p.V1224M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/398 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV55087932; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC6 | c.4190A>G p.D1397G | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV52743974; called by muse, mutect2, varscan2
- ABCC9 | c.3278T>C p.L1093P | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53963362; called by muse, mutect2, varscan2
- ABCC9 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV53971927; called by muse, mutect2, varscan2
- AC011462.1 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV60531757; called by muse, mutect2, varscan2
- ACOT7 | c.865G>A p.V289I (on ENST00000377855 / NM_181864.3; = p.V279I on NM_007274.4) | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs760234992, COSV64113481; called by muse, mutect2, varscan2
- ACSM2A | c.455C>A p.S152Y (on ENST00000219054; = p.S73Y on NM_001308169.2) | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99525373; called by muse, mutect2, varscan2
- ACSS2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.037); catalogued as rs748637375, COSV53624787; called by muse, mutect2, varscan2
- ACTC1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.346); catalogued as COSV51758949; called by muse, mutect2
- ACTL8 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | catalogued as COSV64861465, COSV64862128, COSV64862919; called by muse, mutect2, varscan2
- ACTN4 | c.2619del p.D874Tfs*44 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs869292397; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 80/164 reads (49%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVRL1 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs750085854, CM159681, COSV66360207; called by muse, mutect2, varscan2
- ADAMTS5 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV53179251, COSV99538093; called by muse, mutect2, varscan2
- ADCY10 | c.1389G>T p.W463C | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1465254971, COSV63240942; called by muse, mutect2, varscan2
- ADCY5 | c.3622C>T p.R1208C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750439767, COSV100568353, COSV59198058; called by muse, mutect2, varscan2
- ADGRG5 | c.1485C>T p.Y495= | Splice Region (SNP) | VAF 12/73 reads (16%) | catalogued as rs370635864, COSV61083030; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 42/146 reads (29%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP | c.1478A>G p.Y493C | Missense Mutation (SNP) | VAF 39/478 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1407198440, COSV62425376; called by muse, mutect2
- AGAP3 | c.521C>T p.T174M (on ENST00000622464; = p.T210M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/268 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs369279193; called by muse, mutect2, varscan2
- AGO1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV64594678; called by muse, mutect2, varscan2
- AGO1 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs935068063, COSV64595317; called by muse, mutect2, varscan2
- AHRR | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs866630885, COSV57086307; called by muse, mutect2
- AJM1 | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778041533, COSV56032636; called by muse, mutect2, varscan2
- AK8 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV53754648; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AMBRA1 | c.378+1G>A p.X126_splice | Splice Site (SNP) | VAF 38/163 reads (23%) | catalogued as COSV54054141; called by muse, mutect2, varscan2
- AMOTL2 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs545800849, COSV51439035; called by muse, mutect2, varscan2
- AMY2B | c.525T>G p.C175W | Missense Mutation (SNP) | VAF 86/496 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63715307; called by muse, mutect2, varscan2
- ANAPC2 | c.2130del p.G711Afs*52 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as COSV60568599; called by mutect2, pindel, varscan2
- ANGPTL6 | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53462337; called by muse, mutect2, varscan2
- ANKRD27 | c.1292G>A p.C431Y | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60131700; called by muse, mutect2, varscan2
- ANKRD6 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs768555283, COSV60231560; called by muse, mutect2, varscan2
- APOD | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1167296896, COSV58402017; called by muse, mutect2, varscan2
- APOL6 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.085); catalogued as COSV68749517; called by muse, mutect2, varscan2
- ARAP1 | c.1952G>A p.R651H (on ENST00000393609 / NM_001040118.2; = p.R406H on NM_015242.4) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs201068078; called by muse, mutect2, varscan2
- AREL1 | c.1973_1975del p.F658del | In Frame Del (DEL) | VAF 18/109 reads (17%) | catalogued as rs759474118; called by pindel, varscan2
- ARFGEF3 | c.6026C>T p.A2009V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs866824460, COSV52457691; called by muse, mutect2, varscan2
- ARHGAP12 | c.1876del p.T626Pfs*5 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as rs143153220; called by mutect2, pindel, varscan2
- ARHGAP20 | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs759906371, COSV52810788; called by muse, mutect2, varscan2
- ARHGAP30 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63516586; called by muse, mutect2
- ARHGAP39 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1319412093, COSV52770232; called by muse, mutect2, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 18/97 reads (19%) | catalogued as COSV57429840; called by mutect2, pindel, varscan2
- ARHGEF10L | c.3395G>A p.R1132Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs765652001, COSV51432602; called by muse, mutect2, varscan2
- ARHGEF10L | c.3541G>A p.A1181T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as rs371858468; called by muse, mutect2, varscan2
- ARID1A | c.2017C>T p.Q673* | Nonsense Mutation (SNP) | VAF 30/149 reads (20%) | catalogued as COSV61371349; called by muse, mutect2, varscan2
- ARMC3 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs763504461, COSV53061528; called by muse, mutect2, varscan2
- ARSJ | c.1292del p.N431Mfs*86 | Frame Shift Del (DEL) | VAF 37/195 reads (19%) | catalogued as rs1562327720; called by mutect2, pindel, varscan2
- ASCC3 | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.197); catalogued as COSV61228553; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 26/101 reads (26%) | catalogued as rs747570359; called by mutect2, varscan2
- ASIC1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs368761955; called by muse, mutect2, varscan2
- ATP2B4 | c.3244G>A p.A1082T | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV58177983; called by muse, mutect2, varscan2
- ATP8B3 | c.2264G>T p.S755I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV59542867; called by muse, mutect2, varscan2
- ATXN1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.972); catalogued as rs1232140999, COSV55216826; called by muse, mutect2, varscan2
- AXIN2 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1166843937, COSV61057631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXL | c.1960G>A p.A654T (on ENST00000301178 / NM_021913.5; = p.A645T on NM_001699.6) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.046); catalogued as rs767628105, COSV56568325, COSV56576705; called by muse, mutect2, varscan2
- B2M | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 50/197 reads (25%) | catalogued as COSV62564125; called by muse, mutect2, varscan2
- B3GALNT1 | c.314del p.K105Sfs*14 | Frame Shift Del (DEL) | VAF 55/190 reads (29%) | catalogued as rs759975633; called by mutect2, pindel, varscan2
- BAP1 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56233213, COSV56234530; called by muse, varscan2
- BBS9 | c.2321C>T p.A774V (on ENST00000242067 / NM_001348036.1; = p.A734V on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/318 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.604); catalogued as COSV54168306; called by muse, mutect2, varscan2
- BCAT1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as rs761486552, COSV53911462; called by muse, mutect2, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | catalogued as rs751941533; called by pindel, varscan2
- BPIFB2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs761917219, COSV50066618; called by muse, varscan2
- BPTF | c.8822G>A p.R2941H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs368469411, COSV58833105; called by muse, mutect2, varscan2
- BRIX1 | c.953T>C p.I318T | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV57760660; called by muse, mutect2, varscan2
- C1orf198 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs370439547; called by muse, mutect2, varscan2
- C2orf16 | c.4988G>A p.R1663H | Missense Mutation (SNP) | VAF 127/527 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs577799086, COSV62674724; called by muse, mutect2, varscan2
- C8orf58 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51515256; called by muse, mutect2, varscan2
- C9orf43 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs200902357, COSV55912689; called by muse, mutect2, varscan2
- CA13 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58797866; called by muse, mutect2, varscan2
- CACNA1D | c.2627G>A p.R876H (on ENST00000350061 / NM_001128840.3; = p.R896H on NM_000720.4) | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55438611, COSV99859147; called by muse, mutect2, varscan2
- CACNA1I | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100360705; called by muse, mutect2, varscan2
- CAPG | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1039561537, COSV55707481; called by muse, mutect2, varscan2
- CAPN13 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs368104197; called by muse, mutect2, varscan2
- CARF | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.165); catalogued as COSV57547693; called by muse, mutect2, varscan2
- CARMIL2 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58026386; called by muse, mutect2
- CBFA2T2 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765237844, COSV60074173; called by muse, mutect2, varscan2
- CC2D1A | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs771963034, COSV58783281; called by muse, mutect2, varscan2
- CCDC141 | c.2186A>T p.D729V | Missense Mutation (SNP) | VAF 21/330 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV55373616; called by muse, mutect2
- CCDC170 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.094); catalogued as rs775579048, COSV53340928; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCL19 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1564112971, COSV61337440; called by muse, mutect2, varscan2
- CCT8L2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.069); catalogued as rs573220545, COSV63461652, COSV63464157; called by muse, mutect2, varscan2
- CD209 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs187439891, COSV52649272; called by muse, mutect2, varscan2
- CD300C | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as rs143534670, COSV58170450; called by muse, mutect2, varscan2
- CDC16 | c.779A>G p.K260R | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1281192406, COSV52959608; called by muse, mutect2, varscan2
- CDC40 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1157578965, COSV57009415, COSV57009577; called by muse, mutect2, varscan2
- CDC42BPA | c.4918G>A p.A1640T (on ENST00000334218 / NM_001366019.2; = p.A1627T on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.065); catalogued as rs904725867, COSV62001632; called by muse, mutect2, varscan2
- CDCP1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs750220191, COSV56105509; called by muse, mutect2, varscan2
- CDH22 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.269); catalogued as rs889790598, COSV64837601; called by muse, mutect2, varscan2
- CDH23 | c.2367G>T p.E789D | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54934670; called by muse, mutect2, varscan2
- CDK8 | c.467A>T p.N156I | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67420799; called by muse, mutect2, varscan2
- CELA3B | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV61402841, COSV61404042; called by muse, mutect2, varscan2
- CELF3 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs770229986, COSV51883458; called by muse, mutect2, varscan2
- CELF4 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs769180157, COSV58452460; called by muse, mutect2, varscan2
- CENPF | c.2159A>T p.N720I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65275061, COSV65277125; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 56/278 reads (20%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs747064410; called by mutect2, varscan2
- CEP97 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59124706, COSV59128797; called by muse, mutect2, varscan2
- CHAD | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.979); catalogued as rs778831115, COSV51972492; called by muse, mutect2, varscan2
- CHD3 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs769962813, COSV57875122, COSV57876247; called by muse, mutect2, varscan2
- CHD5 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs1363216674, COSV52414830; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 22/104 reads (21%) | catalogued as rs751548647; called by mutect2, varscan2
- CLCNKB | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376461684; called by muse, mutect2, varscan2
- CLDN23 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1452231517, COSV67731530; called by muse, mutect2, varscan2
- CLSTN1 | c.1294C>T p.R432C (on ENST00000377298 / NM_001009566.3; = p.R422C on NM_014944.4) | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs368470193; called by muse, mutect2, varscan2
- CLSTN2 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs142015908; called by muse, mutect2, varscan2
- CLTRN | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV66711874; called by muse, mutect2, varscan2
- CLVS1 | c.978-2A>G p.X326_splice | Splice Site (SNP) | VAF 32/180 reads (18%) | catalogued as COSV57969890, COSV57975098; called by muse, mutect2, varscan2
- CNGB1 | c.522dup p.K175Qfs*4 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | catalogued as rs1277141710, COSV99209762; called by mutect2, pindel, varscan2
- CNGB3 | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV60689981; called by muse, mutect2, varscan2
- CNR1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as rs777110971, COSV62986868; called by muse, mutect2, varscan2
- CNTNAP2 | c.2120G>T p.W707L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62182918; called by muse, mutect2, varscan2
- COG5 | c.113del p.L38* | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs1417102596; called by mutect2, pindel, varscan2
- COG6 | c.192del p.F64Lfs*21 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | catalogued as rs1566167323; called by mutect2, pindel, varscan2
- COIL | c.485del p.N162Tfs*47 | Frame Shift Del (DEL) | VAF 32/167 reads (19%) | catalogued as rs769265872; called by mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 39/208 reads (19%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL11A2 | c.1601C>T p.A534V (on ENST00000341947 / NM_080680.3; = p.A427V on NM_080679.2) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.932); catalogued as COSV59497044; called by muse, mutect2, varscan2
- COL20A1 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs766008349, COSV58917366; called by muse, mutect2, varscan2
- COL9A3 | c.1041G>T p.E347D | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.956); catalogued as COSV100673431, COSV59652838; called by muse, mutect2
- COMMD4 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as rs563697646, COSV51190424; called by muse, mutect2, varscan2
- CPB2 | c.213dup p.V72Cfs*5 | Frame Shift Ins (INS) | VAF 32/142 reads (23%) | catalogued as rs1174947217; called by mutect2, varscan2
- CPNE5 | c.1772C>T p.T591M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.227); catalogued as rs757357164, COSV55196584; called by muse, mutect2, varscan2
- CPSF1 | c.3567+1G>A p.X1189_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV58233615; called by mutect2, varscan2
- CPT1A | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs368052217; called by muse, mutect2, varscan2
- CPT1C | c.1634T>A p.V545D | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV54919237; called by muse, mutect2
- CRACD | c.1963dup p.R655Pfs*28 | Frame Shift Ins (INS) | VAF 13/57 reads (23%) | catalogued as rs769175297; called by mutect2, pindel
- CREB3 | c.1091T>C p.I364T | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV59207505; called by muse, mutect2, varscan2
- CREB3L2 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV57795176; called by muse, mutect2, varscan2
- CRX | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372219374; called by muse, mutect2, varscan2
- CSDE1 | c.1292C>T p.T431M (on ENST00000358528 / NM_001007553.3; = p.T400M on NM_007158.6) | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as rs377443747; called by muse, mutect2, varscan2
- CSF1R | c.1510+2T>C p.X504_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV53834976; called by muse, mutect2, varscan2
- CSMD2 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs377466001; called by muse, mutect2, varscan2
- CSNK2A2 | c.811A>G p.N271D | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52642011; called by muse, mutect2, varscan2
- CTAG2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); catalogued as rs1304178212, COSV55994984; called by muse, mutect2, varscan2
- CTHRC1 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57715573; called by muse, mutect2, varscan2
- CTSE | c.930del p.V311Wfs*106 (on ENST00000360218; = p.V306Wfs*106 on NM_001910.4) | Frame Shift Del (DEL) | VAF 27/119 reads (23%) | catalogued as COSV63062281; called by mutect2, pindel, varscan2
- CTTNBP2 | c.3917A>G p.K1306R | Missense Mutation (SNP) | VAF 52/390 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.025); catalogued as COSV50402339; called by muse, mutect2, varscan2
- CYP4F22 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758816247, COSV54106236; called by muse, mutect2, varscan2
- DAB2IP | c.2302G>A p.D768N (on ENST00000408936; = p.D740N on NM_032552.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as rs908623993, COSV52259809; called by muse, mutect2, varscan2
- DACT1 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1395278987; called by muse, mutect2
- DCAF13 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as rs774270409, COSV52571921; called by muse, mutect2, varscan2
- DCBLD1 | c.512G>A p.S171N | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV51639377; called by muse, mutect2, varscan2
- DCC | c.4224G>T p.E1408D | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV71432209; called by muse, mutect2, varscan2
- DCLRE1A | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs750179914, COSV63748174; called by muse, mutect2, varscan2
- DCSTAMP | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV52577747; called by muse, mutect2, varscan2
- DCT | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs776332822, COSV65469142; called by muse, mutect2, varscan2
- DDB1 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57102760; called by muse, mutect2, varscan2
- DDI1 | c.443G>A p.S148N | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV56378499; called by muse, mutect2, varscan2
- DDX17 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs960948904, COSV53251009; called by muse, mutect2
- DDX60L | c.3338del p.L1113Cfs*38 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs757771764; called by mutect2, varscan2
- DGKZ | c.3110dup p.E1038Rfs*4 (on ENST00000454345 / NM_001105540.2; = p.E850Rfs*4 on NM_003646.4) | Frame Shift Ins (INS) | VAF 26/136 reads (19%) | catalogued as rs3832759; called by mutect2, varscan2
- DIAPH3 | c.958del p.I320Lfs*20 (on ENST00000400324 / NM_001042517.2; = p.I57Lfs*20 on NM_030932.3) | Frame Shift Del (DEL) | VAF 46/208 reads (22%) | catalogued as rs755069320; called by mutect2, varscan2
- DLEC1 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 24/149 reads (16%) | catalogued as rs377205155; called by muse, mutect2, varscan2
- DLX5 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV56032521; called by muse, mutect2, varscan2
- DNAH10 | c.5891C>T p.T1964M (on ENST00000409039; = p.T1903M on NM_207437.3) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs377607369; called by muse, mutect2, varscan2
- DNAH11 | c.2501T>C p.V834A | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as rs953148212, COSV60956058; called by muse, mutect2, varscan2
- DNAJA3 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52162012; called by muse, mutect2, varscan2
- DNAJC22 | c.734T>C p.L245P | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV67711885; called by muse, mutect2, varscan2
- DNAJC5B | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 76/395 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV52535695, COSV99395865; called by muse, mutect2, varscan2
- DNAJC8 | c.417dup p.Q140Tfs*15 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | catalogued as rs1557706537; called by mutect2, varscan2
- DNTTIP1 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs752890673, COSV54754981; called by muse, mutect2, varscan2
- DOCK5 | c.2546A>T p.D849V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52402127; called by muse, mutect2, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs1239294263; called by mutect2, pindel, varscan2
- DOLK | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as COSV65362236; called by muse, mutect2, varscan2
- DPP6 | c.940G>A p.A314T (on ENST00000377770 / NM_001364500.2; = p.A252T on NM_001936.5) | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs778166866, COSV59599853; called by muse, mutect2
- DQX1 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 92/521 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV66353200; called by muse, mutect2, varscan2
- DTNB | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs1411759513, COSV56476935; called by muse, mutect2, varscan2
- DTX1 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs979063266, COSV57497378; called by muse, mutect2, varscan2
- DVL1 | c.1301G>A p.R434H (on ENST00000378888 / NM_001330311.2; = p.R409H on NM_004421.3) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867732546, COSV59563437; called by muse, mutect2, varscan2
- DYNC1I1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.629); catalogued as rs369627655; called by muse, mutect2, varscan2
- DYNC1I1 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs761416597, COSV61460950; called by muse, mutect2, varscan2
- DZIP1L | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs145919527; called by muse, mutect2, varscan2
- E2F8 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372105528; called by muse, mutect2, varscan2
- EAPP | c.582-1G>T p.X194_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99164244; called by muse, mutect2, varscan2
- EDNRB | c.841A>T p.S281C (on ENST00000377211 / NM_001201397.1; = p.S191C on NM_000115.5) | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs1013425803, COSV57522749; called by muse, mutect2, varscan2
- EED | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as COSV54555566; called by muse, mutect2, varscan2
- EEF1A2 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs1355004578, COSV53206172; called by muse, mutect2, varscan2
- EFTUD2 | c.2259+2T>C p.X753_splice | Splice Site (SNP) | VAF 45/237 reads (19%) | catalogued as COSV53655629; called by muse, mutect2, varscan2
- EHMT2 | c.960_971del p.E320_E323del | In Frame Del (DEL) | VAF 31/139 reads (22%) | catalogued as rs756298483; called by mutect2, varscan2
- ELANE | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55048067; called by muse, mutect2, varscan2
- ELFN2 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs548410357, COSV68744590; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 73/260 reads (28%) | catalogued as rs766700925; called by mutect2, varscan2
- ENHO | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV54281155; called by muse, mutect2, varscan2
- EP400 | c.4489G>A p.A1497T | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as COSV57772394; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 16/80 reads (20%) | catalogued as rs768793415; called by mutect2, varscan2
- ERBB4 | c.2230G>T p.V744L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as COSV53533318; called by muse, mutect2, varscan2
- ERBIN | c.3919C>T p.P1307S (on ENST00000284037 / NM_001253697.2; = p.P1266S on NM_018695.4) | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV52316665; called by muse, mutect2, varscan2
- ERCC2 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV55540787; called by muse, mutect2, varscan2
- ERICH1 | c.346A>T p.K116* | Nonsense Mutation (SNP) | VAF 29/142 reads (20%) | catalogued as COSV50638298; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 26/158 reads (16%) | catalogued as rs775950025; called by mutect2, varscan2
- ETNPPL | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV56595837; called by muse, mutect2
- EVL | c.1025+2T>C p.X342_splice (on ENST00000402714 / NM_001330221.2; = p.X344_splice on NM_016337.3) | Splice Site (SNP) | VAF 17/94 reads (18%) | catalogued as COSV67375366; called by muse, mutect2, varscan2
- EVPL | c.3154C>T p.R1052W | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs745489565, COSV56910669; called by muse, mutect2, varscan2
- EXOC8 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as COSV50478038, COSV50478260; called by muse, mutect2, varscan2
- FAHD2B | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as COSV55630688; called by muse, mutect2, varscan2
- FAM120A | c.3122C>A p.S1041Y | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV52905168; called by muse, mutect2, varscan2
- FAT1 | c.12910G>A p.V4304M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747368128, COSV71674005; called by muse, mutect2, varscan2
- FAT1 | c.6290G>A p.G2097D | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV71674012, COSV71674854; called by muse, mutect2, varscan2
- FBLL1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100606173; called by muse, mutect2, varscan2
- FBXL7 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV61646111; called by muse, mutect2, varscan2
- FBXO30 | c.698T>C p.L233S | Missense Mutation (SNP) | VAF 70/333 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52791293; called by muse, varscan2
- FBXO41 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs771960976, COSV54584631, COSV99721740; called by muse, mutect2, varscan2
- FBXO7 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs61730784, COSV56678208; called by muse, mutect2, varscan2
- FCGBP | c.9382G>A p.V3128M | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs774159833; called by muse, mutect2
- FCRL1 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV63825259; called by muse, mutect2, varscan2
- FFAR1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.943); catalogued as rs200829130, COSV50052941; called by muse, mutect2, varscan2
- FGA | c.1479G>T p.E493D | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57396193; called by muse, mutect2, varscan2
- FGF1 | c.104del p.G35Afs*4 | Frame Shift Del (DEL) | VAF 23/132 reads (17%) | catalogued as COSV61803250; called by mutect2, pindel, varscan2
- FGF22 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1053327160, COSV51260890; called by muse, mutect2, varscan2
- FGGY | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760816361, COSV58033426; called by muse, mutect2, varscan2
- FIBCD1 | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs952429857, COSV53393545; called by muse, mutect2, varscan2
- FILIP1 | c.130A>G p.R44G | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52729910; called by muse, mutect2, varscan2
- FIP1L1 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as rs1182237812, COSV55785103; called by muse, mutect2, varscan2
- FLG | c.10000G>T p.G3334W | Missense Mutation (SNP) | VAF 236/1038 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776910156, COSV100911449, COSV64241987; called by muse, mutect2
- FLNB | c.1133A>G p.D378G | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55879707; called by muse, mutect2, varscan2
- FOXB2 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.688); catalogued as rs373706916, COSV65022976; called by muse, mutect2, varscan2
- FSD2 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as COSV58009539, COSV58010143; called by muse, mutect2, varscan2
- GAD2 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.31); catalogued as rs369617935; called by muse, mutect2, varscan2
- GAPVD1 | c.3718C>T p.R1240W (on ENST00000394104; = p.R1249W on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs759402634, COSV52923114; called by muse, mutect2, varscan2
- GARNL3 | c.2656C>A p.L886I | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV59226396; called by muse, mutect2, varscan2
- GATAD2A | c.817dup p.R273Pfs*58 | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | catalogued as rs1241275301; called by mutect2, pindel, varscan2
- GBA3 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV72438137; called by muse, mutect2, varscan2
- GCN1 | c.5016+1G>C p.X1672_splice | Splice Site (SNP) | VAF 10/76 reads (13%) | catalogued as COSV56107868; called by muse, mutect2, varscan2
- GDF2 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs1438682267; called by muse, mutect2, varscan2
- GDF7 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244819184, COSV55347779; called by muse, mutect2, varscan2
- GJB1 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as rs1244231648, COSV62139637; called by muse, mutect2, varscan2
- GLI1 | c.1978C>A p.L660M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as COSV57362107; called by muse, mutect2, varscan2
- GLIPR1L2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as rs550463995, COSV57553070, COSV57553633; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAT1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.191); catalogued as COSV50029753; called by muse, mutect2, varscan2
- GNPDA1 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs746621093, COSV60942204; called by muse, mutect2, varscan2
- GOLGA6B | c.575G>A p.C192Y | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1304648502, COSV69770130; called by muse, mutect2
- GP2 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs140222432, COSV56893728; called by muse, mutect2, varscan2
- GPATCH4 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV58039758; called by muse, varscan2
- GPD1 | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV56548055; called by muse, mutect2
- GPR139 | c.730del p.R244Afs*4 | Frame Shift Del (DEL) | VAF 39/142 reads (27%) | catalogued as COSV58505701; called by mutect2, pindel, varscan2
- GPR162 | c.1382G>A p.R461K (on ENST00000311268 / NM_019858.2; = p.R177K on NM_014449.2) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV51833226; called by muse, mutect2, varscan2
- GPR17 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.444); catalogued as COSV55755278; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 62/233 reads (27%) | catalogued as rs1416935976; called by mutect2, varscan2
- GRAP2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as rs976111985, COSV100703183, COSV59995241; called by mutect2, varscan2
- GRIA2 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 65/318 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.845); catalogued as COSV52390901, COSV99644249; called by muse, mutect2, varscan2
- GTF3C1 | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1165925220, COSV62241292; called by muse, mutect2, varscan2
- GTF3C1 | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1251882863, COSV62241298; called by muse, mutect2, varscan2
- GUCY2D | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs765886731, COSV54696275; called by muse, mutect2, varscan2
- GUSB | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 86/265 reads (32%) | catalogued as COSV59221940; called by muse, mutect2, varscan2
- HAL | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV54117922; called by muse, mutect2, varscan2
- HARBI1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs562293059, COSV58706095; called by muse, mutect2, varscan2
- HARS1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs550778711, COSV56905701; called by muse, mutect2, varscan2
- HAUS6 | c.2324T>C p.I775T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65840028; called by muse, mutect2, varscan2
- HCRTR1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65485536; called by muse, mutect2, varscan2
- HHATL | c.195G>T p.W65C | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV60041825; called by muse, mutect2, varscan2
- HIC2 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1411123322, COSV68041953, COSV68042101; called by muse, mutect2, varscan2
- HIVEP2 | c.2110G>T p.G704W | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50006365, COSV50013321; called by muse, mutect2, varscan2
- HK1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477873055, COSV53857658; called by muse, mutect2, varscan2
- HKDC1 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1039209123, COSV100664531, COSV63577201; called by muse, mutect2, varscan2
- HOXB3 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs951556409, COSV57486842; called by muse, mutect2, varscan2
- HOXD10 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50891734; called by muse, mutect2, varscan2
- HPS3 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV56054478; called by muse, mutect2, varscan2
- HS6ST3 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); catalogued as rs377277765; called by muse, mutect2, varscan2
- HSF4 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1396328490, COSV50457173; called by muse, mutect2, varscan2
- HSPG2 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 8/97 reads (8%) | catalogued as rs747493127, COSV101012954, COSV65930339; called by muse, mutect2
- HYAL1 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs782751421, COSV56497579; called by muse, mutect2, varscan2
- ICAM2 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56743545; called by muse, mutect2, varscan2
- ICE2 | c.2248A>G p.R750G | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs780462063, COSV55031485; called by muse, mutect2, varscan2
- IFI44 | c.1332del p.K444Nfs*17 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs1309076306; called by mutect2, pindel, varscan2
- IL1B | c.771G>T p.Q257H | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV54521668; called by muse, mutect2, varscan2
- IL20RA | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.823); catalogued as COSV57358393; called by muse, mutect2, varscan2
- INA | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); catalogued as rs1236004257, COSV63975965; called by muse, mutect2, varscan2
- INHA | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.803); catalogued as COSV54719292; called by muse, mutect2, varscan2
- INO80D | c.1540del p.M514Wfs*5 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as COSV68960008; called by mutect2, pindel, varscan2
- INPP5D | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV64037088; called by muse, mutect2, varscan2
- IPO11 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 41/173 reads (24%) | catalogued as COSV57576397; called by muse, mutect2, varscan2
- IREB2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs755226126, COSV51922774; called by muse, mutect2, varscan2
- IRX2 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100121768; called by muse, mutect2, varscan2
- IRX2 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV100121770; called by muse, mutect2, varscan2
- ISL1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57933658; called by muse, mutect2, varscan2
- ISM1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs374878260; called by muse, mutect2, varscan2
- ITGAX | c.2921C>A p.P974H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51645830; called by muse, mutect2, varscan2
- ITPR2 | c.4565G>A p.C1522Y | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs199707449, COSV67269432; called by muse, mutect2, varscan2
- ITPRIP | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs775756816, COSV53391553; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 41/116 reads (35%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JAKMIP1 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.425); catalogued as rs1282195574, COSV51530755; called by muse, mutect2, varscan2
- JPH3 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52467811; called by muse, mutect2, varscan2
- KALRN | c.4169C>T p.A1390V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs759826348, COSV53764530; called by muse, mutect2, varscan2
- KALRN | c.7721G>A p.R2574H (on ENST00000360013 / NM_001024660.4; = p.R877H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs369115824; called by muse, mutect2, varscan2
- KANK1 | c.569T>C p.M190T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs752973772, COSV63212270; called by muse, mutect2, varscan2
- KAT2B | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55429493; called by muse, mutect2, varscan2
- KAT6A | c.5572C>T p.R1858C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374807145; called by muse, mutect2, varscan2
- KCNB1 | c.2325del p.S777Afs*33 | Frame Shift Del (DEL) | VAF 105/650 reads (16%) | catalogued as rs747521886; called by mutect2, pindel, varscan2
- KCND3 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV56180990; called by muse, mutect2, varscan2
- KCND3 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs781094017, COSV56181009; called by muse, mutect2, varscan2
- KCNH6 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV59003498; called by muse, mutect2, varscan2
- KCNH6 | c.2176dup p.R726Pfs*16 | Frame Shift Ins (INS) | VAF 29/145 reads (20%) | catalogued as rs1312956554; called by mutect2, pindel, varscan2
- KCNJ3 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as COSV54531464; called by muse, mutect2, varscan2
- KDM6A | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450363794, COSV65037148; ClinVar: uncertain significance; called by muse, varscan2
- KEAP1 | c.746G>A p.C249Y | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs865938977, COSV50284716; called by muse, mutect2, varscan2
- KIF15 | c.1186T>C p.S396P | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV58160906; called by muse, mutect2, varscan2
- KIF26B | c.2596A>G p.I866V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV63641785; called by muse, mutect2, varscan2
- KIF26B | c.3436G>T p.G1146W | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV63641799; called by muse, mutect2, varscan2
- KLHDC8A | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65678770; called by muse, mutect2, varscan2
- KMT2B | c.2909G>A p.R970Q | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as rs780053167, COSV55861164; called by muse, mutect2, varscan2
- KMT2C | c.9465A>G p.I3155M | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.174); catalogued as COSV51440566; called by muse, mutect2, varscan2
- KRCC1 | c.547del p.S183Afs*7 | Frame Shift Del (DEL) | VAF 31/150 reads (21%) | catalogued as rs1326358542; called by mutect2, varscan2
- KRTAP4-3 | c.73T>C p.C25R | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66940707; called by muse, mutect2, varscan2
- KSR2 | c.2124G>T p.K708N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56672734; called by muse, mutect2, varscan2
- L3MBTL1 | c.1391G>A p.R464H (on ENST00000418998 / NM_001377303.1; = p.R374H on NM_015478.7) | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559497364, COSV64228227; called by muse, mutect2, varscan2
- LAMA3 | c.5512G>A p.E1838K (on ENST00000313654 / NM_198129.4; = p.E229K on NM_000227.6) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.396); catalogued as rs533403846, COSV52534876; called by muse, mutect2, varscan2
- LAMB3 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61916944; called by muse, mutect2, varscan2
- LANCL2 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs569807357, COSV54649370; called by muse, mutect2, varscan2
- LDHD | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372223577, COSV55580867; called by muse, mutect2, varscan2
- LMCD1 | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV50088405; called by muse, mutect2, varscan2
- LONP1 | c.2801A>G p.H934R | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.376); catalogued as COSV56798400; called by muse, mutect2, varscan2
- LPAR6 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.796); catalogued as COSV57308052; called by muse, mutect2, varscan2
- LRFN3 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs912468422, COSV55817736; called by muse, mutect2, varscan2
- LRRC4B | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV65349610, COSV65350566; called by muse, mutect2, varscan2
- LRRC8A | c.2086A>G p.N696D | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.111); catalogued as COSV52185846; called by muse, mutect2, varscan2
- LRRN2 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs749764096, COSV65783455; called by muse, mutect2, varscan2
- LRRTM3 | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as COSV63665609; called by muse, mutect2, varscan2
- LTF | c.553T>A p.F185I | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV51608115; called by muse, varscan2
- LUZP4 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 80/186 reads (43%) | catalogued as COSV64218934; called by muse, mutect2, varscan2
- MAP1A | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745720733, COSV55808928; called by muse, mutect2, varscan2
- MAP7D1 | c.1862G>A p.R621Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs1350318794, COSV60216403; called by muse, mutect2, varscan2
- MAPK3 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53773602; called by muse, mutect2, varscan2
- MAST2 | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs772807759, COSV63618267; called by muse, mutect2, varscan2
- MBD1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs771787035, COSV53998883; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 22/105 reads (21%) | catalogued as rs746267361; called by mutect2, varscan2
- MBLAC2 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV57302201; called by muse, mutect2, varscan2
- MCCC2 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.085); catalogued as COSV100040373; called by muse, mutect2, varscan2
- MCM3 | c.2020C>T p.R674C (on ENST00000229854 / NM_001366374.2; = p.R664C on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs143308289; called by muse, mutect2, varscan2
- MFSD1 | c.163+2T>C p.X55_splice | Splice Site (SNP) | VAF 23/69 reads (33%) | catalogued as COSV51840773; called by muse, mutect2, varscan2
- MGAT1 | c.710G>A p.C237Y | Missense Mutation (SNP) | VAF 33/188 reads (18%) | PolyPhen probably damaging (1); catalogued as COSV57134081; called by muse, mutect2, varscan2
- MICU3 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 36/245 reads (15%) | catalogued as rs1333364327, COSV58844852; called by muse, mutect2, varscan2
- MINDY2 | c.1847del p.N616Ifs*41 | Frame Shift Del (DEL) | VAF 29/125 reads (23%) | catalogued as rs1282883369; called by mutect2, pindel, varscan2
- MLF2 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs973096788, COSV52571255; called by muse, mutect2, varscan2
- MMP14 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as rs757252435, COSV61288288, COSV99043494; called by muse, mutect2, varscan2
- MOCOS | c.1988A>C p.E663A | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV54343480; called by muse, mutect2, varscan2
- MPDZ | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100063170; called by muse, mutect2, varscan2
- MPEG1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.44); catalogued as rs775131648, COSV57090863; called by muse, mutect2, varscan2
- MRPL2 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52435832; called by muse, mutect2, varscan2
- MSLN | c.1386del p.S463Afs*33 (on ENST00000382862 / NM_013404.4; = p.S455Afs*33 on NM_005823.6) | Frame Shift Del (DEL) | VAF 29/130 reads (22%) | catalogued as rs780605061; called by mutect2, pindel, varscan2
- MTMR14 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs377332766, COSV56003299; called by muse, mutect2, varscan2
- MUC16 | c.24667C>T p.P8223S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV67466821; called by muse, mutect2, varscan2
- MUC5B | c.15718G>A p.A5240T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV71592085; called by muse, mutect2, varscan2
- MUSK | c.581dup p.N194Kfs*16 | Frame Shift Ins (INS) | VAF 41/231 reads (18%) | catalogued as rs1395885868; called by mutect2, pindel, varscan2
- MVB12B | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV63258518; called by muse, mutect2, varscan2
- MXD1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as rs762511553, COSV52479669, COSV52481339; called by muse, mutect2
- MYEOV | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs568014391, COSV58294292; called by muse, mutect2, varscan2
- MYH10 | c.1451A>T p.Q484L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV52601260; called by muse, mutect2, varscan2
- MYH7B | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53419228; called by muse, mutect2, varscan2
- MYH8 | c.4297C>A p.L1433I | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101238307, COSV67965336; called by muse, mutect2, varscan2
- MYH9 | c.2127del p.N710Tfs*15 | Frame Shift Del (DEL) | VAF 48/216 reads (22%) | catalogued as COSV53391892; called by mutect2, pindel, varscan2
- MYOC | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.027); catalogued as COSV50674907; called by muse, mutect2, varscan2
- MYOM3 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs746030427, COSV58393914; called by muse, mutect2, varscan2
- MYOM3 | c.2916A>G p.I972M | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58393935; called by muse, mutect2, varscan2
- MYOM3 | c.2858+2T>C p.X953_splice | Splice Site (SNP) | VAF 58/263 reads (22%) | catalogued as rs910729169, COSV58393953; called by muse, mutect2, varscan2
- MYT1L | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV67715720; called by muse, mutect2, varscan2
- NAAA | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs777433295, COSV54432217; called by muse, mutect2, varscan2
- NAGK | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54903617; called by muse, mutect2, varscan2
- NAV3 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV57080572, COSV99889464; called by muse, mutect2, varscan2
- NBN | c.1689G>T p.L563F | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55373208; called by muse, varscan2
- NCSTN | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1357632342, COSV54187691; called by muse, mutect2, varscan2
- NEMF | c.2593G>A p.V865M | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as rs756950161, COSV53591646; called by muse, mutect2, varscan2
- NEPRO | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV55606524; called by muse, mutect2, varscan2
- NFE2 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56455892; called by muse, mutect2, varscan2
- NFXL1 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs746582969, COSV61198993; called by muse, mutect2, varscan2
- NIBAN2 | c.2216G>A p.S739N | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.154); catalogued as COSV55940095; called by muse, mutect2
- NKTR | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1342796754, COSV51771769; called by muse, varscan2
- NLRC5 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV52655235; called by muse, mutect2, varscan2
- NOTCH1 | c.5026G>A p.V1676I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1261408162, COSV53025911; called by muse, mutect2, varscan2
- NOTCH2 | c.3205C>T p.R1069W | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs61752485, COSV56691666; called by muse, mutect2, varscan2
- NPC1L1 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV56925188; called by muse, mutect2, varscan2
- NRAP | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 93/424 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs1341131885, COSV63490671; called by muse, varscan2
- NRBP1 | c.1447+2T>C p.X483_splice | Splice Site (SNP) | VAF 16/76 reads (21%) | catalogued as COSV51994218; called by muse, mutect2, varscan2
- NRL | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53744192; called by muse, mutect2
- NRROS | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV60745949; called by muse, mutect2
- NRXN2 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs536698209, COSV55453255; called by muse, mutect2, varscan2
- NSD1 | c.4127C>A p.P1376H | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1431048535, COSV61776481; called by muse, mutect2, varscan2
- NT5DC1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs751232489, COSV60308858; called by muse, mutect2, varscan2
- NTSR1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.071); catalogued as rs1355950959, COSV65138661; called by muse, mutect2, varscan2
- NUAK2 | c.1324del p.L442Cfs*38 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as rs753375361; called by mutect2, pindel, varscan2
- NYAP1 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55718868; called by muse, mutect2, varscan2
- OARD1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs777911574, COSV55107755; called by muse, mutect2, varscan2
- ODF2L | c.1349dup p.N450Kfs*52 (on ENST00000317336; = p.N421Kfs*52 on NM_020729.3) | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | catalogued as COSV99643707; called by mutect2, pindel, varscan2
- ODF3L2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774779124, COSV52746048; called by muse, mutect2, varscan2
- OLFM2 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as rs1351549792, COSV53430368; called by muse, mutect2, varscan2
- OR10AG1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs758408014, COSV56632974; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1E1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59458981; called by muse, mutect2, varscan2
- OR2AG2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV58455203; called by muse, mutect2, varscan2
- OR2J3 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs372756606; called by muse, mutect2, varscan2
- OR2M2 | c.265A>G p.S89G | Missense Mutation (SNP) | VAF 130/597 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV62898388; called by muse, mutect2, varscan2
- OR4B1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs758861637, COSV58882172, COSV58882854; called by muse, mutect2, varscan2
- OR4B1 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV58882861; called by muse, mutect2, varscan2
- OR51G1 | c.761A>G p.Y254C | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245916624, COSV58969243; called by muse, mutect2, varscan2
- OR52I2 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); catalogued as COSV57045033; called by muse, mutect2, varscan2
- OR52R1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139182026; called by muse, mutect2, varscan2
- OR5J2 | c.439G>T p.G147* | Nonsense Mutation (SNP) | VAF 28/139 reads (20%) | catalogued as COSV56621332; called by muse, mutect2, varscan2
- OR5T1 | c.855A>G p.I285M | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.34); catalogued as COSV57302741; called by muse, mutect2, varscan2
- OR6C65 | c.305dup p.L102Ffs*18 | Frame Shift Ins (INS) | VAF 36/151 reads (24%) | catalogued as rs753853776; called by mutect2, varscan2
- OSM | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs200749557, COSV53161347; called by muse, mutect2, varscan2
- OSMR | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.15); catalogued as COSV57085223; called by muse, mutect2, varscan2
- P3H1 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199597388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs763394045; called by mutect2, varscan2
- PABPC4 | c.1202T>C p.F401S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV63293402; called by muse, mutect2, varscan2
- PAFAH2 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 69/305 reads (23%) | catalogued as rs144717482; called by muse, mutect2, varscan2
- PAK6 | c.1589A>G p.D530G | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53045656; called by muse, mutect2, varscan2
- PAN2 | c.3422G>A p.R1141H (on ENST00000425394 / NM_001127460.3; = p.R1137H on NM_014871.5) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs749136909, COSV56263804; called by muse, mutect2, varscan2
- PAN3 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 37/137 reads (27%) | catalogued as COSV56703082; called by muse, varscan2
- PAPSS1 | c.1067G>A p.W356* | Nonsense Mutation (SNP) | VAF 88/395 reads (22%) | catalogued as COSV54489203, COSV54490507; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PARP1 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 87/440 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as rs774530658, COSV64690473; called by muse, mutect2, varscan2
- PARP3 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs1267960887, COSV51754387; called by muse, varscan2
- PAX4 | c.692T>A p.L231H | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58388903; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | catalogued as CM011452; called by mutect2, varscan2
- PAXBP1 | c.2524G>A p.G842R | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV51609144; called by muse, mutect2, varscan2
- PBX4 | c.1063del p.Q355Nfs*25 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as rs748202447; called by mutect2, pindel, varscan2
- PBXIP1 | c.896T>C p.L299P | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63777209; called by muse, mutect2, varscan2
- PC | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63080656; called by muse, mutect2, varscan2
- PCDHA2 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.16); catalogued as rs782611214, COSV65367093, COSV65367638; called by muse, mutect2, varscan2
- PCDHA8 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100968879, COSV65323689; called by muse, mutect2, varscan2
- PCDHAC1 | c.1450C>A p.L484M | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53849904; called by muse, mutect2, varscan2
- PCDHAC2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53848370; called by muse, mutect2, varscan2
- PCDHB11 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs782123077, COSV61311634; called by muse, mutect2, varscan2
- PCDHGA12 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.035); catalogued as rs202246871; called by muse, mutect2, varscan2
- PCDHGA5 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1165362537, COSV53949849; called by muse, mutect2
- PCDHGC3 | c.2050del p.R684Gfs*15 | Frame Shift Del (DEL) | VAF 35/324 reads (11%) | catalogued as rs764598056; called by mutect2, pindel, varscan2
- PCNX1 | c.4427C>T p.A1476V | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53094914; called by muse, mutect2, varscan2
- PDCD11 | c.3260C>T p.T1087M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs745919550, COSV63934022; called by muse, mutect2, varscan2
- PDCL3 | c.629A>G p.E210G | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51809246; called by muse, mutect2, varscan2
- PDE10A | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV63092716; called by muse, mutect2, varscan2
- PDE6B | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs757048461, COSV55326588; called by mutect2, varscan2
- PDIA2 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs376852015, COSV51987692; called by muse, mutect2, varscan2
- PFKP | c.793del p.R265Gfs*2 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as rs1161592176; called by mutect2, pindel, varscan2
- PGBD2 | c.89T>C p.M30T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61400227; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHLPP2 | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748202550, COSV62424530; called by muse, mutect2, varscan2
- PIGO | c.1361del p.G454Vfs*31 | Frame Shift Del (DEL) | VAF 46/287 reads (16%) | catalogued as COSV53054111, COSV53054694; called by mutect2, pindel, varscan2
- PIK3CA | c.2636A>G p.Q879R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV55928531; called by muse, mutect2, varscan2
- PKD1L1 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56965245; called by muse, mutect2, varscan2
- PLA2G4F | c.824dup p.I276Hfs*44 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | catalogued as rs762798872; called by pindel, varscan2
- PLCB3 | c.3057G>T p.E1019D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV54188616; called by muse, mutect2, varscan2
- PLCZ1 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1256344296, COSV56852789; called by muse, mutect2, varscan2
- PLEC | c.13757C>T p.A4586V (on ENST00000322810 / NM_201380.4; = p.A4476V on NM_000445.5) | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs782720210, COSV59637477; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHM1 | c.857A>G p.E286G | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV69598881; called by muse, mutect2, varscan2
- PLPPR2 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs765334902, COSV52260001; called by muse, mutect2, varscan2
- PLXNC1 | c.3652C>T p.R1218W | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1458455411, COSV51575500; called by muse, mutect2, varscan2
- PLXND1 | c.2632C>T p.R878W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs141047735; called by muse, mutect2, varscan2
- PMEL | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs746019205, COSV59385111; called by muse, mutect2, varscan2
- PNMA8B | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV66536631; called by muse, mutect2
- PNPLA8 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57552467; called by muse, mutect2, varscan2
- POGLUT1 | c.1094A>T p.E365V | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV55156698; called by muse, mutect2, varscan2
- POGZ | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1166733985, COSV55035855; called by muse, mutect2, varscan2
- POLR1A | c.4486G>A p.E1496K | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.353); catalogued as rs1039399945, COSV55692015; called by muse, mutect2, varscan2
- POLR3C | c.148-1G>C p.X50_splice | Splice Site (SNP) | VAF 37/121 reads (31%) | catalogued as COSV61936596; called by muse, mutect2, varscan2
- POLR3C | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV61936592; called by muse, mutect2, varscan2
- POU3F2 | c.43A>G p.S15G | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV60408940; called by muse, mutect2, varscan2
- PPTC7 | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62826177; called by muse, mutect2, varscan2
- PRKAG1 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 30/135 reads (22%) | catalogued as rs376578148; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 32/113 reads (28%) | catalogued as rs753236928; called by mutect2, varscan2
- PRRC2B | c.3535C>T p.R1179W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469607536; called by muse, mutect2
- PRSS55 | c.756del p.P253Lfs*18 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | catalogued as rs751829343; called by mutect2, pindel, varscan2
- PSMA1 | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs747082500, COSV67165947; called by muse, varscan2
- PSMB8 | c.446C>T p.S149L (on ENST00000374882 / NM_148919.4; = p.S145L on NM_004159.5) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs773754392, COSV62754466; called by muse, mutect2, varscan2
- PSMC4 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50095227; called by muse, mutect2, varscan2
- PTK2B | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs369239201, COSV100594282; called by muse, mutect2, varscan2
- PTPA | c.943G>A p.A315T (on ENST00000337738 / NM_178001.2; = p.A280T on NM_021131.5) | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV61234969; called by muse, mutect2, varscan2
- PTPN6 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59684535, COSV59684602; called by muse, mutect2, varscan2
- PUM1 | c.314_316del p.N105del | In Frame Del (DEL) | VAF 28/186 reads (15%) | catalogued as rs1378499024; called by pindel, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB3GAP2 | c.2635C>T p.L879F | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV62784031; called by muse, mutect2, varscan2
- RAF1 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as COSV50105176; called by muse, mutect2, varscan2
- RALGDS | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV64427295; called by muse, varscan2
- RBFOX1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 132/482 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.036); catalogued as rs779321097, COSV60957098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM48 | c.402del p.K134Nfs*9 | Frame Shift Del (DEL) | VAF 31/184 reads (17%) | catalogued as rs754768719; called by mutect2, pindel, varscan2
- RBPJL | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV59213708; called by muse, mutect2, varscan2
- RECK | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776820138, COSV65035419; called by muse, mutect2, varscan2
- REXO1 | c.3232C>T p.R1078C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1352723443, COSV50078145; called by muse, mutect2, varscan2
- RGS12 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs777223492, COSV58749195; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 26/133 reads (20%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS12 | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs200575024, COSV58749223; called by muse, mutect2, varscan2
- RHCE | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV53800501; called by muse, mutect2, varscan2
- RIF1 | c.3143A>G p.D1048G | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1224654355, COSV54617188; called by muse, mutect2, varscan2
- RIMS2 | c.1676C>T p.A559V (on ENST00000666250 / NM_001348490.2; = p.A367V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.093); catalogued as COSV51682440, COSV51731865; called by muse, varscan2
- RIN3 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374091561; called by muse, mutect2, varscan2
- RITA1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1251384095, COSV55321611; called by muse, mutect2, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 36/180 reads (20%) | catalogued as rs760343057; called by mutect2, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs745408248; called by mutect2, varscan2
- RNF175 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.835); catalogued as rs561299972, COSV56841401, COSV56842349; called by muse, mutect2, varscan2
- RNF213 | c.11779G>A p.A3927T | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs777402744, COSV60397739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 27/70 reads (39%) | catalogued as rs745519558; called by mutect2, varscan2
- ROBO4 | c.2656G>A p.A886T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs371221952; called by muse, mutect2, varscan2
- ROM1 | c.545G>T p.W182L | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53882453; called by muse, mutect2, varscan2
- RPL3 | c.742C>A p.L248M | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53365377; called by muse, mutect2, varscan2
- RPL7A | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV59298322; called by muse, mutect2, varscan2
- RPN2 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 25/151 reads (17%) | catalogued as COSV52905657; called by muse, mutect2, varscan2
- RRH | c.324del p.F108Lfs*18 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs751964437; called by mutect2, varscan2
- RTTN | c.2993T>C p.V998A | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV55345045; called by muse, mutect2, varscan2
- RUSC1 | c.2270G>A p.R757H (on ENST00000368352 / NM_001105203.2; = p.R288H on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs768034492, COSV52738156; called by muse, mutect2, varscan2
- RUVBL2 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV55485267; called by muse, mutect2, varscan2
- RYR2 | c.10525A>G p.I3509V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV63686260; called by muse, mutect2, varscan2
- RYR3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774050928, COSV66776549; called by muse, mutect2, varscan2
- RYR3 | c.10670T>C p.L3557P (on ENST00000389232; = p.L3558P on NM_001036.6) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66789789; called by muse, mutect2, varscan2
- S1PR2 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.905); catalogued as rs773248254, COSV58485410; called by muse, mutect2, varscan2
- SALL4 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1184036360, COSV53852349; called by muse, mutect2, varscan2
- SAP130 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52097278; called by muse, varscan2
- SATB1 | c.388+2T>C p.X130_splice | Splice Site (SNP) | VAF 62/287 reads (22%) | catalogued as COSV58669547; called by muse, mutect2, varscan2
- SBF2 | c.3451C>T p.R1151W | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140550985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC23IP | c.1101+2T>C p.X367_splice | Splice Site (SNP) | VAF 30/90 reads (33%) | catalogued as COSV64831559; called by muse, mutect2, varscan2
- SEL1L2 | c.884_886del p.G295del | In Frame Del (DEL) | VAF 8/87 reads (9%) | catalogued as rs766550471; called by pindel, varscan2
- SEMA3D | c.57del p.P20Lfs*3 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as rs1562826346; called by mutect2, pindel, varscan2
- SEZ6L2 | c.1448C>A p.P483Q (on ENST00000308713 / NM_001114099.3; = p.P413Q on NM_012410.4) | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV58099469; called by muse, mutect2, varscan2
- SF1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); catalogued as COSV57113823; called by muse, mutect2, varscan2
- SF3B3 | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56787688; called by muse, mutect2, varscan2
- SFPQ | c.1831C>T p.R611* | Nonsense Mutation (SNP) | VAF 16/244 reads (7%) | catalogued as rs774720675, COSV61758691; called by muse, mutect2
- SH2B1 | c.1901C>T p.P634L (on ENST00000322610 / NM_001308293.1; = p.T667= on NM_015503.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs747265054, COSV59463080; called by muse, mutect2, varscan2
- SH2B2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV60826338; called by muse, mutect2, varscan2
- SH2D3A | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs535033168, COSV55586061; called by muse, mutect2, varscan2
- SH3PXD2A | c.2756A>G p.N919S (on ENST00000369774 / NM_001365079.1; = p.N891S on NM_014631.2) | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60117228; called by muse, mutect2, varscan2
- SIGLEC1 | c.3401T>C p.I1134T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV52463932; called by muse, mutect2, varscan2
- SIK2 | c.2329G>A p.V777I | Missense Mutation (SNP) | VAF 115/564 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as rs1431896790, COSV59250320; called by muse, mutect2, varscan2
- SIPA1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.747); catalogued as rs1452206638, COSV63136852; called by muse, mutect2
- SLC10A6 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV56721665; called by muse, mutect2, varscan2
- SLC12A1 | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.852); catalogued as COSV57709618; called by muse, mutect2, varscan2
- SLC12A6 | c.617del p.L206Yfs*28 (on ENST00000354181 / NM_001365088.1; = p.L155Yfs*28 on NM_005135.2) | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | catalogued as rs916571899; called by mutect2, pindel, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | catalogued as rs767964038; called by mutect2, varscan2
- SLC14A1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552191196, COSV58931576; called by muse, mutect2, varscan2
- SLC15A3 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV57171728; called by muse, mutect2
- SLC17A2 | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.042); catalogued as COSV55352100; called by muse, mutect2, varscan2
- SLC18A1 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759912369, COSV52348170, COSV99368562; called by muse, mutect2, varscan2
- SLC22A23 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs199592727, COSV66677557; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs749849908; called by pindel, varscan2
- SLC23A3 | c.1354C>T p.R452* (on ENST00000409878 / NM_001144889.2; = p.R335* on NM_144712.5) | Nonsense Mutation (SNP) | VAF 83/363 reads (23%) | catalogued as rs368233276; called by muse, mutect2, varscan2
- SLC25A23 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs758854413, COSV51191538; called by muse, mutect2, varscan2
- SLC26A4 | c.965del p.N322Ifs*22 | Frame Shift Del (DEL) | VAF 43/117 reads (37%) | catalogued as rs747834704; called by mutect2, pindel, varscan2
- SLC27A5 | c.1811G>A p.G604D | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.225); catalogued as rs1362016523, COSV54019686; called by muse, mutect2, varscan2
- SLC38A6 | c.1291-1G>T p.X431_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV50781450, COSV50782424; called by muse, mutect2
- SLC4A2 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs781096714, COSV100055130, COSV59657156; called by muse, mutect2, varscan2
- SLC5A6 | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs142905141; called by muse, mutect2, varscan2
- SLC7A10 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs375602222; called by muse, mutect2, varscan2
- SLC9A7 | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV60380255; called by muse, mutect2, varscan2
- SLFNL1 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs569404071, COSV57234643; called by muse, mutect2
- SLITRK1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV65675639; called by muse, mutect2, varscan2
- SLITRK3 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV53845401, COSV53849374; called by muse, mutect2, varscan2
- SLITRK6 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68389797, COSV68390247; called by muse, mutect2, varscan2
- SMARCA4 | c.2995G>A p.D999N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs1555779989, COSV60789368, COSV60804439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC1B | c.572del p.N191Ifs*2 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | catalogued as rs748761052; called by mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs760667210; called by mutect2, varscan2
- SMNDC1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as rs1470044017, COSV63651821; called by muse, mutect2, varscan2
- SMS | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | catalogued as COSV65113753; called by muse, mutect2
- SNX30 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV65292996; called by muse, mutect2, varscan2
- SOGA3 | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 49/181 reads (27%) | catalogued as COSV64106601; called by muse, mutect2, varscan2
- SOHLH2 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65901970; called by muse, mutect2, varscan2
- SP8 | c.808C>T p.H270Y (on ENST00000361443 / NM_198956.4; = p.H288Y on NM_182700.6) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV63866269; called by muse, mutect2, varscan2
- SPATA17 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV65121989; called by muse, mutect2, varscan2
- SPEN | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764932472, COSV65361911; called by muse, mutect2, varscan2
- SPNS3 | c.1517G>A p.G506D | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs371632968, COSV61070094; called by muse, mutect2, varscan2
- SPOP | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.322); catalogued as COSV61654009; called by muse, mutect2, varscan2
- SPRR1B | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV61067660; called by muse, mutect2, varscan2
- SPTAN1 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as rs753283021, COSV63987193; called by muse, mutect2, varscan2
- SRCAP | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796432, COSV52672771; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRP68 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57162665; called by muse, mutect2
- SRSF5 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67936623; called by muse, mutect2, varscan2
- ST3GAL4 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.65); catalogued as rs11559148, COSV57105749; called by muse, mutect2, varscan2
- STAG1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 35/398 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV52610203; called by muse, mutect2
- STK25 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs75331794, COSV50869965; called by muse, mutect2, varscan2
- STX1A | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV56108661, COSV56109147; called by muse, varscan2
- SUSD5 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs552801817, COSV58877765; called by muse, mutect2
- SVOPL | c.976dup p.D326Gfs*18 (on ENST00000419765; = p.D174Gfs*18 on NM_174959.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 23/144 reads (16%) | catalogued as rs769304357; called by mutect2, varscan2
- SYCP1 | c.173del p.N58Mfs*34 | Frame Shift Del (DEL) | VAF 21/118 reads (18%) | catalogued as rs1482391429; called by mutect2, pindel, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs753462162; called by mutect2, varscan2
- SYCP2L | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV51653234, COSV99305394; called by muse, mutect2, varscan2
- SYNE1 | c.10769G>A p.R3590Q (on ENST00000367255 / NM_182961.4; = p.R3597Q on NM_033071.3) | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs762304790, COSV54937242; called by muse, mutect2, varscan2
- SYNE1 | c.780C>T p.D260= (on ENST00000367255 / NM_182961.4; = p.D267= on NM_033071.3) | Splice Region (SNP) | VAF 13/55 reads (24%) | catalogued as rs376480815; called by muse, mutect2, varscan2
- SYNE3 | c.2902C>T p.R968C | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs764718779, COSV62079499; called by muse, mutect2, varscan2
- SYNPO2L | c.1112G>T p.G371V (on ENST00000394810 / NM_001114133.3; = p.G147V on NM_024875.5) | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV65736980; called by muse, mutect2, varscan2
- TAAR6 | c.412del p.L138Wfs*47 | Frame Shift Del (DEL) | VAF 97/527 reads (18%) | catalogued as rs1347997031; called by mutect2, pindel, varscan2
- TACC3 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.369); catalogued as rs142494551; called by muse, mutect2
- TAF6 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV59841684; called by muse, mutect2, varscan2
- TBC1D9B | c.1328_1330del p.F443del | In Frame Del (DEL) | VAF 24/120 reads (20%) | catalogued as rs777128426; called by mutect2, pindel, varscan2
- TBCCD1 | c.1109T>C p.L370P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV58662217; called by muse, mutect2, varscan2
- TBX2 | c.590dup p.Q198Afs*5 | Frame Shift Ins (INS) | VAF 17/119 reads (14%) | catalogued as COSV99538558; called by mutect2, pindel, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 142/327 reads (43%) | catalogued as rs763321097; called by mutect2, varscan2
- TECPR2 | c.863A>G p.H288R | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV63970655; called by muse, mutect2, varscan2
- TESPA1 | c.689C>T p.T230I (on ENST00000316577 / NM_001098815.3; = p.T92I on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV57258966; called by muse, mutect2, varscan2
- TEX13A | c.1044del p.H350Tfs*3 | Frame Shift Del (DEL) | VAF 35/82 reads (43%) | catalogued as COSV61186225; called by mutect2, pindel, varscan2
- TEX15 | c.6011T>C p.L2004S (on ENST00000256246; = p.L2387S on NM_001350162.2) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56346716; called by muse, mutect2, varscan2
- THBS1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367736106; called by muse, mutect2, varscan2
- THRAP3 | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs780659896, COSV63567313; called by muse, mutect2, varscan2
- TIMD4 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50855489; called by muse, mutect2, varscan2
- TJP2 | c.1678A>G p.T560A | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV55266911; called by muse, mutect2, varscan2
- TMC7 | c.1415A>T p.D472V | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV58583614; called by muse, mutect2, varscan2
- TMCO6 | c.1316T>C p.V439A | Missense Mutation (SNP) | VAF 86/418 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as COSV52799821; called by muse, mutect2, varscan2
- TMEFF2 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV55832839; called by muse, mutect2, varscan2
- TMEM151A | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV59173810; called by muse, mutect2, varscan2
- TMEM200C | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs778993065, COSV67309481; called by muse, mutect2, varscan2
- TMEM63A | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.964); catalogued as COSV55300900; called by muse, mutect2, varscan2
- TMEM64 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747707548, COSV69127804; called by muse, mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 32/166 reads (19%) | catalogued as rs747222326; called by mutect2, pindel, varscan2
- TNC | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as rs757368961, COSV60783689; called by mutect2, varscan2
- TNFRSF13B | c.869del p.G290Afs*34 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as rs752255870, COSV55425520; called by mutect2, pindel, varscan2
- TNFRSF1B | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs765864632, COSV66164293; called by muse, mutect2, varscan2
- TNRC18 | c.2339C>T p.T780M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs762510718, COSV68165546; called by muse, mutect2, varscan2
- TRABD2A | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs759830766, COSV59105641; called by muse, mutect2, varscan2
- TRAM2 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.034); catalogued as COSV51732734; called by muse, mutect2, varscan2
- TRAP1 | c.378del p.K126Nfs*38 | Frame Shift Del (DEL) | VAF 19/134 reads (14%) | catalogued as COSV55917784; called by mutect2, pindel, varscan2
- TRIM17 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs147756265; called by muse, mutect2, varscan2
- TRIM32 | c.1526G>A p.C509Y | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV57778682; called by muse, mutect2, varscan2
- TRIM39 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.012); catalogued as COSV64955401; called by muse, mutect2, varscan2
- TRIM6 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs374195536, COSV53476220; called by muse, mutect2, varscan2
- TRIM62 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs758671290, COSV52221413; called by muse, mutect2, varscan2
- TRIM71 | c.2156C>T p.T719M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs909650325, COSV67470440; called by muse, mutect2, varscan2
- TRMT2A | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV52813505; called by muse, mutect2
- TRPM4 | c.2778+2T>C p.X926_splice | Splice Site (SNP) | VAF 25/80 reads (31%) | catalogued as rs1456714344, COSV53262888; called by muse, mutect2, varscan2
- TSGA13 | c.452del p.K151Sfs*2 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | catalogued as rs782528606, COSV58404193; called by mutect2, varscan2
- TSHZ1 | c.2230A>G p.N744D (on ENST00000580243 / NM_001308210.2; = p.N699D on NM_005786.6) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV59009497; called by muse, mutect2, varscan2
- TSPEAR | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs1569169775, COSV59962670; called by muse, mutect2, varscan2
- TTC22 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64881388; called by muse, mutect2
- TTC37 | c.412A>T p.T138S | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as COSV62454823; called by muse, mutect2, varscan2
- TTC7A | c.2289G>T p.E763D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV55411229; called by muse, mutect2, varscan2
- TTI1 | c.1547_1548del p.V516Gfs*11 | Frame Shift Del (DEL) | VAF 22/120 reads (18%) | catalogued as rs1221954004; called by pindel, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.8399del p.K2800Sfs*5 (on ENST00000591111; = p.K2754Sfs*5 on NM_003319.4) | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | catalogued as COSV60219516; called by mutect2, pindel, varscan2
- TTYH3 | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51860274; called by muse, mutect2, varscan2
- TULP4 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65575749; called by muse, mutect2, varscan2
- TXLNA | c.614A>C p.N205T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV65314166, COSV65314350; called by muse, mutect2, varscan2
- UBE4A | c.2027T>G p.L676R (on ENST00000252108 / NM_001204077.2; = p.L683R on NM_004788.4) | Missense Mutation (SNP) | VAF 80/307 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52804242, COSV52805499; called by muse, mutect2, varscan2
- UBE4B | c.2320C>T p.R774C (on ENST00000343090 / NM_001105562.3; = p.R645C on NM_006048.5) | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs765404233, COSV53532556; called by muse, mutect2, varscan2
- UGT1A4 | c.517del p.W173Gfs*8 | Frame Shift Del (DEL) | VAF 74/312 reads (24%) | catalogued as rs780658532; called by mutect2, pindel, varscan2
- ULK1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs751254383, COSV58856799; called by muse, mutect2, varscan2
- ULK4 | c.1778del p.K593Rfs*17 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs76318575; called by mutect2, varscan2
- UMODL1 | c.3092G>A p.G1031D (on ENST00000408910 / NM_001004416.2; = p.G1159D on NM_173568.3) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV68569833; called by muse, mutect2, varscan2
- UNC5A | c.1490C>A p.T497N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52840084; called by muse, mutect2, varscan2
- UNCX | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.59); PolyPhen probably damaging (0.997); catalogued as COSV60333165; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs767420916; called by mutect2, varscan2
- URGCP | c.2789G>A p.R930Q (on ENST00000453200 / NM_001077663.3; = p.R921Q on NM_017920.4) | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as rs750425699, COSV56247847; called by muse, mutect2, varscan2
- USB1 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV54683108; called by muse, mutect2, varscan2
- VANGL2 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.871); catalogued as rs757893266, COSV100925511, COSV63604501; called by muse, mutect2, varscan2
- VAT1 | c.571A>G p.S191G | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1395899059, COSV63040042; called by muse, mutect2, varscan2
- VCP | c.1847del p.N616Mfs*63 | Frame Shift Del (DEL) | VAF 26/123 reads (21%) | catalogued as rs751290466; called by mutect2, varscan2
- VCPIP1 | c.1148A>G p.D383G | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV60047344; called by muse, mutect2, varscan2
- VNN1 | c.689A>C p.D230A | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63389955; called by muse, mutect2, varscan2
- VXN | c.439G>T p.G147* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100560049; called by muse, mutect2, varscan2
- WDR17 | c.3913G>T p.A1305S | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs770701279, COSV54574312; called by muse, mutect2, varscan2
- WNT9B | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1270343087, COSV51518485; called by muse, mutect2, varscan2
- XAB2 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV64321706; called by muse, mutect2, varscan2
- XCR1 | c.40del p.Y14Tfs*33 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | catalogued as rs1158688440; called by mutect2, varscan2
- XPO5 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs764867205, COSV54830134, COSV99541387; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 18/131 reads (14%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YAE1 | c.32A>G p.Q11R | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56232990; called by muse, mutect2, varscan2
- YTHDF3 | c.686G>A p.S229N | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs746387401, COSV72773499; called by muse, mutect2, varscan2
- ZBTB45 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs1473456549, COSV54019691; called by muse, mutect2, varscan2
- ZBTB8A | c.626del p.K209Rfs*5 | Frame Shift Del (DEL) | VAF 19/139 reads (14%) | catalogued as rs1253124144; called by mutect2, pindel, varscan2
- ZC3H10 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as COSV57769125; called by muse, mutect2, varscan2
- ZC3H12D | c.701C>A p.P234H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66324397; called by muse, mutect2, varscan2
- ZC3H6 | c.588del p.K196Nfs*4 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | catalogued as COSV59671010; called by mutect2, pindel, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs745875253; called by mutect2, varscan2
- ZEB2 | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV57957008; called by muse, mutect2, varscan2
- ZFP37 | c.498del p.K166Nfs*19 | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | catalogued as COSV100953148; called by mutect2, pindel, varscan2
- ZFYVE16 | c.445T>A p.L149I | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1225685997, COSV62015780; called by muse, mutect2, varscan2
- ZHX3 | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 46/188 reads (24%) | catalogued as rs1320639895, COSV58383599; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1538G>A p.C513Y | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561941844, COSV52852564; called by muse, mutect2, varscan2
- ZNF107 | c.1732A>G p.N578D | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs59947864, COSV61328713; called by muse, mutect2, varscan2
- ZNF142 | c.1499G>A p.R500H (on ENST00000411696 / NM_001379660.1; = p.R300H on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs767653049, COSV68743769; called by muse, mutect2, varscan2
- ZNF175 | c.2005A>G p.R669G | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV51795712; called by muse, mutect2, varscan2
- ZNF292 | c.3310G>T p.G1104* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as COSV60539519; called by muse, mutect2, varscan2
- ZNF318 | c.3346C>T p.R1116C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757137064, COSV58932675; called by muse, mutect2, varscan2
- ZNF319 | c.1214A>G p.Q405R | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.725); catalogued as COSV54621610; called by muse, mutect2, varscan2
- ZNF366 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs368259666, COSV59219124; called by muse, mutect2, varscan2
- ZNF490 | c.776T>C p.F259S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61008058; called by muse, mutect2, varscan2
- ZNF492 | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV71761972; called by muse, mutect2, varscan2
- ZNF540 | c.820A>G p.K274E | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV57109339; called by muse, mutect2
- ZNF583 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.68); catalogued as COSV52402520; called by muse, mutect2, varscan2
- ZNF599 | c.1303A>G p.S435G | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV61396209; called by muse, mutect2, varscan2
- ZNF618 | c.547A>C p.S183R (on ENST00000374126 / NM_001318042.2; = p.S151R on NM_133374.2) | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV55921512; called by muse, mutect2, varscan2
- ZNF76 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs551762842, COSV57591475; called by muse, varscan2
- ZNF761 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as rs561986415, COSV61888360; called by muse, mutect2, varscan2
- ZNF784 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV57596049; called by muse, varscan2
- ZNF98 | c.306T>A p.N102K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1568289712, COSV63335140, COSV63335366; called by muse, mutect2, varscan2
- ZNFX1 | c.2869C>T p.R957C | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs377053417; called by muse, mutect2, varscan2
- ZNFX1 | c.1547G>T p.R516M | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65574957; called by muse, mutect2, varscan2
- ABHD15 | c.979del p.S327Afs*44 | Frame Shift Del (DEL) | VAF 21/128 reads (16%) | called by mutect2, pindel, varscan2
- ABITRAM | c.184del p.T62Qfs*31 | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | called by mutect2, pindel, varscan2
- ACP1 | c.372del p.K124Nfs*61 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- ACTL6B | c.149del p.G50Afs*40 | Frame Shift Del (DEL) | VAF 15/101 reads (15%) | called by mutect2, pindel, varscan2
- ADNP2 | c.3135del p.K1045Nfs*29 | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | called by mutect2, pindel, varscan2
- AFF2 | c.82del p.R28Gfs*30 | Frame Shift Del (DEL) | VAF 87/192 reads (45%) | called by mutect2, varscan2
- AFG3L2 | c.255del p.A86Lfs*99 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- AGPAT5 | c.772dup p.I258Nfs*6 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- AKAP13 | c.2012_2013del p.T671Sfs*4 | Frame Shift Del (DEL) | VAF 32/245 reads (13%) | called by pindel, varscan2
- AOC1 | c.1864del p.L622Wfs*3 | Frame Shift Del (DEL) | VAF 41/146 reads (28%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- ARSJ | c.1735_1736del p.K579Efs*32 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- ASPSCR1 | c.491dup p.S165Qfs*104 | Frame Shift Ins (INS) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- ATP2A1 | c.2682del p.E895Sfs*3 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- ATP2B4 | c.2684dup p.T896Yfs*14 | Frame Shift Ins (INS) | VAF 35/142 reads (25%) | called by mutect2, pindel, varscan2
- ATXN7 | c.2340del p.T781Pfs*11 | Frame Shift Del (DEL) | VAF 30/135 reads (22%) | called by mutect2, pindel, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- BOC | c.704del p.P235Qfs*47 | Frame Shift Del (DEL) | VAF 53/305 reads (17%) | called by mutect2, pindel, varscan2
- BPGM | c.280dup p.A94Gfs*16 | Frame Shift Ins (INS) | VAF 18/133 reads (14%) | called by mutect2, pindel, varscan2
- CAMSAP2 | c.3789dup p.Q1264Tfs*12 (on ENST00000236925 / NM_001297707.2; = p.Q1253Tfs*12 on NM_203459.3) | Frame Shift Ins (INS) | VAF 29/135 reads (21%) | called by mutect2, varscan2
- CDC42BPG | c.1425del p.P477Qfs*67 | Frame Shift Del (DEL) | VAF 30/176 reads (17%) | called by mutect2, pindel, varscan2
- CDCP1 | c.2162dup p.F722Vfs*9 | Frame Shift Ins (INS) | VAF 41/417 reads (10%) | called by mutect2, pindel
- CDH8 | c.286del p.I96Sfs*16 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- CFAP65 | c.1896del p.M633* | Frame Shift Del (DEL) | VAF 46/210 reads (22%) | called by mutect2, pindel, varscan2
- CFTR | c.3889del p.S1297Lfs*31 | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | called by mutect2, pindel, varscan2
- CLEC12B | c.455del p.N152Ifs*22 | Frame Shift Del (DEL) | VAF 27/146 reads (18%) | called by mutect2, pindel, varscan2
- COPS4 | c.96del p.A33Pfs*10 | Frame Shift Del (DEL) | VAF 23/99 reads (23%) | called by mutect2, pindel, varscan2
- CPEB1 | c.1846del p.L616* (on ENST00000617958; = p.L551* on NM_030594.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- CPLANE1 | c.7646del p.K2549Rfs*4 | Frame Shift Del (DEL) | VAF 34/144 reads (24%) | called by mutect2, pindel, varscan2
- CTNND1 | c.1346dup p.N449Kfs*3 | Frame Shift Ins (INS) | VAF 131/624 reads (21%) | called by mutect2, pindel, varscan2
- CWF19L2 | c.2127dup p.H710Afs*11 | Frame Shift Ins (INS) | VAF 14/102 reads (14%) | called by mutect2, pindel, varscan2
- DCAF1 | c.2976del p.K992Nfs*16 | Frame Shift Del (DEL) | VAF 83/423 reads (20%) | called by mutect2, pindel, varscan2
- DCUN1D5 | c.303dup p.T102Yfs*15 | Frame Shift Ins (INS) | VAF 30/132 reads (23%) | called by mutect2, pindel, varscan2
- DDX39B | c.447del p.F149Lfs*13 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | called by mutect2, varscan2
- DLG2 | c.774_775del p.H258Qfs*28 | Frame Shift Del (DEL) | VAF 35/205 reads (17%) | called by mutect2, pindel, varscan2
- DNAJC9 | c.664_665del p.S222Qfs*56 | Frame Shift Del (DEL) | VAF 36/184 reads (20%) | called by pindel, varscan2
- DSC2 | c.1625del p.N542Mfs*29 | Frame Shift Del (DEL) | VAF 50/242 reads (21%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.7881_7883del p.P2628del | In Frame Del (DEL) | VAF 21/168 reads (13%) | called by mutect2, pindel, varscan2
- EOMES | c.995del p.G332Afs*4 | Frame Shift Del (DEL) | VAF 62/342 reads (18%) | called by mutect2, pindel, varscan2
- ERBB4 | c.1130del p.P377Lfs*8 | Frame Shift Del (DEL) | VAF 35/226 reads (15%) | called by mutect2, pindel, varscan2
- FAAP24 | c.17del p.P6Lfs*41 | Frame Shift Del (DEL) | VAF 33/196 reads (17%) | called by mutect2, pindel, varscan2
- FAM209B | c.102dup p.K35Efs*46 | Frame Shift Ins (INS) | VAF 48/301 reads (16%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1417del p.R473Efs*25 (on ENST00000281708 / NM_001349798.2; = p.R393Efs*25 on NM_018315.5) | Frame Shift Del (DEL) | VAF 50/256 reads (20%) | called by mutect2, pindel, varscan2
- FRRS1 | c.370del p.T124Qfs*20 | Frame Shift Del (DEL) | VAF 25/114 reads (22%) | called by mutect2, pindel, varscan2
- GAL3ST1 | c.874del p.E292Sfs*110 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- GCNT2 | c.595del p.T199Pfs*5 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | called by mutect2, pindel, varscan2
- GDF10 | c.614A>G p.D205G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPA33 | c.883_884dup p.E296Gfs*81 | Frame Shift Ins (INS) | VAF 20/126 reads (16%) | called by mutect2, varscan2
- GPT2 | c.51del p.S18Afs*36 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- HAUS8 | c.1029del p.S344Afs*86 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- HEATR5A | c.1000del p.S334Lfs*4 | Frame Shift Del (DEL) | VAF 23/123 reads (19%) | called by mutect2, pindel, varscan2
294 further variants in this file (78 protein-altering or splice-affecting, 197 silent, 19 other) are not listed here.
